Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5466, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5466-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED] Report Status: Amend/
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

PATIENT: [REDACTED]

TCGA-CZ-5466

PATHOLOGIC DIAGNOSIS:

A) RIGHT KIDNEY, NEPHRECTOMY:
RENAL CELL CARCINOMA, clear cell type, Fuhrman grade II (8.8 cm),
limited to the kidney.
Renal vein invasion is present.
Margins of soft tissue, renal vein, ureter, and renal artery are
negative for tumor.
AJCC Classification (6th edition): T3 Nx Mx.
The non-neoplastic kidney will be evaluated by Renal Pathology, and the
findings will be reported in an addendum.

B) SPECIMEN LABELED "RIGHT RETROPERITONEAL LYMPH NODES":
Adipose and vascular tissue with no tumor present.

CLINICAL DATA:

History: None given.
Operation: Right radical nephrectomy
Operative Findings: Not provided.
Clinical Diagnosis: Right renal mass.

TISSUE SUBMITTED:

A/1) Tumor and kidney (T.B.)
B/2) Right retroperitoneal lymph nodes.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, labeled "#1. Tumor and kidney (T.B.)", consists of a 183-gram right radical nephrectomy specimen (18.5 x 16.0 x 13.5 cm) with surrounding perirenal fat (measuring in thickness from 1.5 to 3.5 cm). Extending from the renal pelvis is a ureter (8.5 cm in length x 0.4 cm in diameter, renal artery (1.5 cm in length x 0.6 cm in diameter) and renal vein (0.8 cm in length x 0.9 cm in diameter). Ninety (90%) percent of the renal parenchyma is replaced by multicystic mass composed of necrotic cyst with calcified rim, abutting but not invading the capsule (up to 10.5 x 8.5 x 6.5 cm). Adjacent to the necrotic cyst are viable tan/orange heterogeneous tumor masses with small areas of necrosis (measuring 8.8 x 7.0 x 6.5 cm). This mass also abuts but does not invade the capsule or perirenal fat. The tumor protrudes into the renal vein and is 0.6 cm from the vein margin. The remainder of the renal cortex is tan/brown. The pelvis is covered by smooth glistening mucosa. The perirenal adipose tissue is thinly sectioned and no lymph nodes are found. No tissue consistent with adrenal gland was identified. Representative sections of tumor have been submitted for tissue bank and cytogenetics. Representative sections of normal renal parenchyma have been submitted for IM and EM.

[page 2 of 3]
Pathology Report

CGA-CZ-5466

The kidney parenchyma was evaluated by Dr. [REDACTED] Renal Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A7) were evaluated using H&E, PAS, Jones' silver methenamine, and AFOG (trichrome) stains. The sample consists of cortex and medulla. Significant amount of tumor is present in this sample, and the parenchyma sample is located very close to the tumor. There are 200 glomeruli present, of which 22 (11.0%) are globally sclerosed. The remaining glomeruli show no significant expansion of the mesangial areas. There are no discernible craters or double contours of the glomerular capillary wall basement membranes. The interstitium shows edema and marked focal inflammatory infiltrates consisting mostly of mononuclear inflammatory cells and occasional eosinophils and neutrophils. Tubules reveal moderate invasion of the tubular epithelial cell layer by mononuclear inflammatory cells (tubulitis). There are also several hyaline casts and cellular debris within the tubular lumen. Approximately 50% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit marked of the wall and of the subintima sclerosis.

[REDACTED]

[page 3 of 3]
Pathology Report

Accession Number: [REDACTED]
Type: Cytogenetics

Report Status: Final

PATIE
Cytogeneticist: [REDACTED]

KARYOTYPE: 45,X,-Y[4]/46,XY[11]

METAPHASES COUNTED: 15 ANALYZED: 6 SCORED: 9 BANDING: GTG

INTERPRETATION:

Four of 15 metaphases contained loss of the Y chromosome, but this is not necessarily representative of a neoplastic population, as loss of the Y chromosome is a common finding in older men.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:
RCC

Source: NCI Genomic Data Commons file 6898841c-7aa9-4723-a44d-440afdfbe158 (TCGA-CZ-5466.A4DFE5B5-27B4-49BB-99AA-87261FE267EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).